Somatic mutation profile of tumor specimen C3N-02380-01 (aliquot CPT0146680010) from CPTAC case C3N-02380, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 56.1 years (20,483 days).
Specimen C3N-02380-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d985f138-0bf0-48ec-8a67-1acbd0f38ca9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02380-71 (Blood Derived Normal), aliquot CPT0146710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f026c60-e426-4b05-938a-b446d76e3494

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, 3'UTR 3, Nonsense Mutation 2, 3'Flank 1, Intron 1, 5'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 83/408 reads (20%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- HPD | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 38/556 reads (7%) | catalogued as rs367674632, COSV100000000; ClinVar: pathogenic; called by muse, mutect2
- ABCC8 | c.2143G>C p.V715L | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as CD061344; called by muse, mutect2, varscan2
- ADGRV1 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 166/403 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67979670; called by muse, mutect2, varscan2
- CRACD | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as rs1181305797; called by muse, mutect2
- CRNN | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 28/530 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs754777109; called by muse, mutect2
- CRYBG2 | c.3269T>C p.L1090P | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100366544; called by muse, mutect2
- CYB5R3 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1362518180, COSV61544904, COSV61545688; called by muse, mutect2, varscan2
- DENND1C | c.1631A>C p.E544A | Missense Mutation (SNP) | VAF 23/296 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs775199669; called by muse, mutect2
- HPSE2 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 68/379 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100985430; called by muse, mutect2, varscan2
- PDX1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1297553641; called by muse, mutect2
- PHF20 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV59185268; called by muse, mutect2
- SNX33 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs766961204; called by muse, mutect2, varscan2
- SPAG17 | c.3220C>T p.H1074Y | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60459632; called by muse, mutect2
- VCAN | c.8579C>A p.S2860Y | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV99425555; called by muse, mutect2
- ZFAND4 | c.298A>G p.M100V | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs1212211253; called by muse, mutect2, varscan2
- ABCC8 | c.3137C>A p.A1046E | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ADGRV1 | c.1059G>C p.E353D | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CAND1 | c.526A>T p.I176F | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CLPX | c.1415T>C p.I472T | Missense Mutation (SNP) | VAF 35/348 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CYP24A1 | c.463T>A p.W155R | Missense Mutation (SNP) | VAF 60/714 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- DNAH14 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 11/309 reads (4%) | called by muse, mutect2
- EPHA8 | c.1432T>C p.Y478H | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2
- GPAT2 | c.1123C>G p.R375G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HACE1 | c.1322G>A p.C441Y | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LPCAT2 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 20/257 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.02); called by muse, mutect2
- NIPSNAP1 | c.286C>G p.P96A | Missense Mutation (SNP) | VAF 59/504 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- PIBF1 | c.67A>G p.I23V | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.084); called by muse, mutect2
- POLK | c.1767T>G p.N589K | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.035); called by muse, mutect2
- SMAD4 | c.1109T>A p.V370D | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SUSD2 | c.2152A>T p.S718C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- TANGO6 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- THAP4 | c.512T>G p.L171R | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.001); called by muse, mutect2
- THG1L | c.415T>C p.F139L | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.392); called by muse, mutect2
- TMEM114 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TNRC6C | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- TSNAX | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- TUBE1 | c.1175A>C p.H392P | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.808); called by muse, mutect2
- UNC13A | c.3293C>T p.A1098V | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- UNC5D | c.1615A>G p.R539G | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF605 | c.196A>G p.M66V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- ACSL5 | c.1896T>C p.L632= (on ENST00000354273; = p.L688= on NM_016234.3) | Silent (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- CMYA5 | c.9351A>G p.G3117= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as rs1268894830; called by muse, mutect2
- DGKZ | c.1527C>T p.L509= (on ENST00000454345 / NM_001105540.2; = p.L321= on NM_003646.4) | Silent (SNP) | VAF 10/280 reads (4%) | called by muse, mutect2
- GUCY1A2 | c.1509C>A p.A503= | Silent (SNP) | VAF 28/256 reads (11%) | called by muse, mutect2, varscan2
- LDB3 | c.1539C>T p.T513= | Silent (SNP) | VAF 38/281 reads (14%) | catalogued as rs1380193786; called by muse, mutect2, varscan2
- MTMR10 | c.33C>T p.F11= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- SLC12A7 | c.1911C>T p.Y637= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as rs372553468; called by muse, mutect2, varscan2
- TEX38 | c.324C>T p.P108= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs369089422; called by muse, mutect2, varscan2
- TXNDC2 | c.357C>T p.I119= (on ENST00000306084 / NM_001098529.2; = p.I52= on NM_032243.6) | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as rs780167884, COSV100045638; called by muse, mutect2
- UGT1A8 | c.390C>T p.D130= | Silent (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- AK2 | chr1:33008160 T>C | 3'Flank (SNP) | VAF 27/317 reads (9%) | called by muse, mutect2
- GYG2P1 | n.274A>G | RNA (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- MATR3 | c.*1388T>C | 3'UTR (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
- SLC35G2 | c.*23T>C | 3'UTR (SNP) | VAF 4/68 reads (6%) | catalogued as rs1560023587; called by muse, mutect2
- SNX27 | c.1519-17A>T | Intron (SNP) | VAF 22/193 reads (11%) | called by muse, mutect2, varscan2
- TENT5A | chr6:81752771 G>A | 5'Flank (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2
- TTC1 | c.*325C>T | 3'UTR (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
